Surgical pathology report (de-identified scan), TCGA case TCGA-85-8276, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8276-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

d Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
[REDACTED]					LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 2.5 x 2 x 4 cm Histologic type: Squamous cell carcinoma, keratinizing Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 3/12 positive for metastasis (Hilar 3/12) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified

[page 2 of 2]
[REDACTED]	Excision date	Laterality
ca ID		
[REDACTED]	[REDACTED]	Left- upper

Source: NCI Genomic Data Commons file 36b3af3e-06db-4bc2-a921-1777947e1c93 (TCGA-85-8276.F51FF537-CBEF-46EF-BED9-B8AD20B8D2F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).